CCDI case PBCGLY — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Adrenal gland.
https://portal.gdc.cancer.gov/cases/c29ed0b1-bbf5-4ddf-a9c2-872c0df83e5f

Demographics
Sex at birth: female; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Paraganglioma, NOS: ICD-O-3 morphology code: 8680/1; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 16.8 years (6,148 days).

Biospecimens (3 samples)
- Sample 0DRXE1: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DRXEI: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DRXEO: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
